Gene-level copy-number profile of tumor specimen TCGA-C5-A1BK-01B from TCGA case TCGA-C5-A1BK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 36.4 years (13,297 days).
Specimen TCGA-C5-A1BK-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5c39ff92-65c2-47e7-8780-ce7158aa3548.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1BK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c4a9fb9-2013-45fb-b24c-93f51b4b888c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 85; copy number 2: 5,277; copy number 3: 31; copy number 4: 46,968; copy number 5: 284; copy number 6: 5,469; copy number 7: 433; copy number 8: 4; copy number 9: 1,123; copy number 10: 37; copy number 11: 75; copy number 13: 14; copy number 17: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1BK-01B-11D-A13V-01): tumor purity 0.46, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:205,681,990–205,798,133, 2 genes: NRP2, AC007362.1.
- chr20:14,884,250–15,552,885, 6 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,259 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,259,687–153,500,764, 14 genes, copy number 13: LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P.
- chr3:138,608,606–198,222,513, 1,044 genes, copy number 9–10 (broad region; genes not listed).
- chr8:9,091,240–9,091,508, 1 gene, copy number 10: Metazoa_SRP.
- chr11:98,565,074–105,531,697, 90 genes, copy number 9–17 (broad region; genes not listed).
- chr15:97,876,289–101,933,350, 110 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 85. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
